Somatic mutation profile of tumor specimen 0DPL7O from CCDI case PBCDBV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.1 years (5,510 days).
Specimen 0DPL7O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5926896f-9f0a-4046-b2ab-f35891620ead.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPL7G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c0aeef0-733b-4c6f-9d29-38c410b8c964

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 5, 3'UTR 4, Silent 3, Splice Region 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 73/742 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs369083450; called by muse, mutect2, varscan2
- CNTNAP3B | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 114/1638 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1373340542; called by muse, mutect2
- LRRC8E | c.709_711del p.K237del | In Frame Del (DEL) | VAF 37/264 reads (14%) | catalogued as rs764885450; called by mutect2, varscan2
- NHS | c.3207T>A p.D1069E | Missense Mutation (SNP) | VAF 166/759 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66272699; called by muse, mutect2, varscan2
- NPBWR2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 96/880 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538624857; called by muse, mutect2, varscan2
- PRICKLE3 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 150/618 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1557100232; called by muse, mutect2, varscan2
- SETD1A | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 132/724 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.158); catalogued as COSV52692225; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 68/1062 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 24/199 reads (12%) | called by muse, varscan2
- HKDC1 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 107/799 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PAXIP1 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPP6R3 | c.1139T>A p.F380Y (on ENST00000393800 / NM_001352375.2; = p.F329Y on NM_018312.5) | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, varscan2
- ZKSCAN1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 40/990 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- PHIP | c.5073A>T p.T1691= | Silent (SNP) | VAF 83/388 reads (21%) | catalogued as rs571545144; called by muse, varscan2
- RPL4 | c.444T>G p.P148= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, varscan2
- SLF1 | c.750A>G p.Q250= | Silent (SNP) | VAF 28/604 reads (5%) | called by muse, mutect2
- ADAMTS2 | c.-19C>T | 5'UTR (SNP) | VAF 81/374 reads (22%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 24/180 reads (13%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 18/168 reads (11%) | called by muse, varscan2
- FRA10AC1 | c.*50T>A | 3'UTR (SNP) | VAF 27/272 reads (10%) | catalogued as rs1317249854; called by muse, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 12/90 reads (13%) | called by muse, varscan2
- GTF2A1 | c.*23A>T | 3'UTR (SNP) | VAF 22/194 reads (11%) | called by muse, varscan2
- LSM14A | c.*123G>T | 3'UTR (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, varscan2
- TXNRD1 | c.305-25T>A | Intron (SNP) | VAF 116/465 reads (25%) | called by muse, mutect2, varscan2
